Surgical pathology report (de-identified scan), TCGA case TCGA-BA-6871, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-6871-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number : [REDACTED]

Diagnosis:

A: Base of tongue, left, biopsy

- Invasive squamous cell carcinoma moderately differentiated

B: Base of tongue, right, biopsy

- Invasive moderately differentiated squamous cell carcinoma

C: Additional base of tongue, right, curettage

- Invasive moderately differentiated squamous cell carcinoma

Intraoperative Consult Diagnosis:

A frozen section was requested by [REDACTED] in OR [REDACTED]

FSA1: Tongue, left base, biopsy

- Invasive squamous cell carcinoma

([REDACTED])

Frozen Section Pathologist:, [REDACTED] [REDACTED]

:

[REDACTED] with tongue base cancer. No path here.

Gross Description:

Specimen A is received fresh for frozen section diagnosis labeled "left base of tongue" and is a 4 x 4 x 3 mm aggregate of tan/pink soft tissue entirely [REDACTED] zen as FSA1, [REDACTED].

Specimen B is received in a formalin-filled container labeled "right base of tongue" and is an unoriented 2.2 x 1.5 x 0.4 cm soft friable pink/tan tissue fragment. One surface is glistening and appears intact and the opposite surface is friable and pink/tan. The intact glistening surface is marked with blue ink.

The specimen is se [REDACTED] ly sectioned and entirely submitted in blocks B1 and B2, [REDACTED]

[page 2 of 2]
Specimen C is received in a formalin-filled container labeled "additional right base of tongue" and is a 2.7 x 2.1 x 0.6 cm aggregate of marked _____ auterized fragments of dark red/brown tissue, C1 and C2, _____

Light Microscopy:

Light microscopic examination is performed by _____

Source: NCI Genomic Data Commons file d916ccd6-2391-4ce5-ba57-6fd6f6b0d2f8 (TCGA-BA-6871.419D6FB8-62C5-4007-81BB-04DC5BDC0732.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).